Gene-level copy-number profile of tumor specimen TCGA-OR-A5J2-01A from TCGA case TCGA-OR-A5J2, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 44.1 years (16,090 days).
Specimen TCGA-OR-A5J2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.6f0290b0-4cb4-4f72-853e-9ac363bd2c3b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5J2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4efbb399-3111-4b0c-b260-5eac67c48320

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 489; copy number 2: 2,614; copy number 3: 39,715; copy number 4: 2,343; copy number 5: 3,179; copy number 6: 11,364; copy number 7: 80.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5J2-01A-11D-A29H-01): tumor purity 0.89, ploidy 1.3, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:247,754,846–247,939,659, 12 genes: OR1C1, OR9H1P, OR14A16, HSD17B7P1, OR6R1P, OR11L1, TRIM58, OR2W3, OR2T8, OR2AJ1, CLK3P2, OR2X1P.
- chr2:25,227,855–25,697,188, 6 genes (within-gene range 0–3): DNMT3A, MIR1301, ARNILA, DTNB, DTNB-AS1, Y_RNA.
- chr5:64,165,843–64,675,387, 6 genes: RNF180, AC091862.1, RGS7BP, RN7SL169P, RNU6-294P, MRPL49P1.
- chr5:98,576,341–98,929,007, 8 genes: CTBP2P4, DDX18P4, RGMB, RGMB-AS1, AC008522.1, CSNK1A1P3, CHD1, RNU6-402P.
- chr5:98,936,638–98,936,747, 1 gene: Y_RNA.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 80 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:43,112,629–43,566,001, 1 gene, copy number 7 (within-gene range 4–7): HECW1.
- chr7:43,508,728–45,873,082, 79 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 466. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
